Gene-level copy-number profile of tumor specimen ALCH-B46T-TTP1-A from ALCHEMIST case ALCH-B46T, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.6 years (23,943 days).
Specimen ALCH-B46T-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a06f703e-a461-458d-bdc6-db23220c8d2a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B46T-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,237 have no estimate.
https://portal.gdc.cancer.gov/files/4e154664-e88f-4fb3-9443-0ca3f3b39770

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 432; copy number 2: 53,937; copy number 3: 3,949; copy number 4: 61; copy number 5: 6; copy number 9: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,884,740–89,887,247, 2 genes, copy number 5: IGKV1D-37, IGKV2D-36.
- chr9:64,621,560–64,709,311, 3 genes, copy number 5: AQP7P2, AL445665.1, BMS1P11.
- chr14:18,333,726–18,341,859, 1 gene, copy number 9: CR383658.1.
- chr14:18,418,775–18,419,273, 1 gene, copy number 5: BNIP3P6.

Autosomal genes at a single copy (total copy number 1): 432. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
